Surgical pathology report (de-identified scan), TCGA case TCGA-78-7162, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7162-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

A : RIGHT UPPER LOBECTOMY

Previous FNA bx [REDACTED] : well differentiated adeno-
carcinoma ? alveolar cell carcinoma.

Macroscopy:

Specimen consists of right upper lobe measuring 23 x 12 x 8
cm. Cut section reveals an irregularly shaped grey mass
measuring 4 cm in diameter. A few peribronchial lymph nodes
are present, the largest 1.5 cm.

Microscopy:

Sections show invasive neoplastic tissue in the pulmonary
parenchyma, composed of sheets of atypical epithelial cells
with a tendency to form papillae. PAS-diastase, PAS/Alcian
blue and CEA are positive.

/Over

SUMMARY:

FEATURES ARE COMPATIBLE WITH BRONCHIOLAR-ALVEOLAR CARCINOMA

B : HILAR LYMPH NODE

Macroscopy:

Specimen consists of lymph node measuring 1 cm.

Microscopy:

Sections show chronic inflammatory changes in lymph nodes.
No evidence of malignancy.

[REDACTED] [REDACTED]

[page 2 of 2]
Pathologist:

Registrar:

Report validated by pathologist/registrar

Archive Report

Source: NCI Genomic Data Commons file 45631ecc-380c-4113-8cae-6824ca6e793f (TCGA-78-7162.41E3D123-0A90-43E4-80B7-7BE47DE9FD16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).